Somatic mutation profile of tumor specimen TCGA-M9-A5M8-01A (aliquot TCGA-M9-A5M8-01A-11D-A28B-09) from TCGA case TCGA-M9-A5M8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.7 years (21,433 days).
Specimen TCGA-M9-A5M8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4897bf7d-9b02-4834-af9b-06fdda743af6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-M9-A5M8-10A (Blood Derived Normal), aliquot TCGA-M9-A5M8-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7412d474-6e01-4080-b0ce-691f05e7f51e

The open-access MAF lists 83 somatic variants for this specimen: 60 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 20, Splice Site 4, Nonsense Mutation 4, Frame Shift Ins 2, Intron 2, Frame Shift Del 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.457+2T>C p.X153_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | hotspot (GDC flag); catalogued as COSV58683976, COSV58692776; called by muse, mutect2, varscan2
- MYOC | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74315334, CM971022, COSV50675840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AK9 | c.5168C>T p.A1723V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.448); catalogued as rs753059975, COSV69850273; called by muse, mutect2, varscan2
- ALOX5 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs754256319, COSV65550760; called by muse, mutect2, varscan2
- ARMCX1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs1556027227; called by muse, mutect2, varscan2
- ARRB1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs74550237, COSV63576098; called by muse, varscan2
- CILP2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as rs754649866, COSV52279833; called by muse, mutect2, varscan2
- CNTNAP5 | c.76A>T p.T26S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs1001531565; called by muse, mutect2, varscan2
- CYP1A1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as rs368952331; called by muse, mutect2, varscan2
- DENND2C | c.708dup p.Y237Ifs*3 | Frame Shift Ins (INS) | VAF 21/62 reads (34%) | catalogued as rs771378748; called by mutect2, pindel, varscan2
- DHTKD1 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553531625; called by muse, mutect2, varscan2
- GRIK1 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58733943; called by muse, mutect2, varscan2
- HDAC6 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as rs782747542, COSV61928888; called by muse, mutect2, varscan2
- HIF3A | c.1159C>T p.R387W (on ENST00000377670 / NM_152795.4; = p.R318W on NM_022462.4) | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs145421578, COSV52202458; called by muse, mutect2, varscan2
- KRTAP9-2 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 76/1082 reads (7%) | catalogued as COSV100893168; called by muse, mutect2
- KRTAP9-9 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 97/537 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.794); catalogued as rs920531114, COSV67453899; called by muse, mutect2, varscan2
- LRG1 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as rs142551012, COSV56705021; called by muse, mutect2, varscan2
- MASTL | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as rs563122532, COSV60911165; called by muse, mutect2, varscan2
- MYCL | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768216635, COSV65693368; called by muse, mutect2, varscan2
- NAV3 | c.3369_3371del p.V1124del | In Frame Del (DEL) | VAF 15/53 reads (28%) | catalogued as rs1566161974; called by pindel, varscan2
- NID1 | c.2260G>A p.V754M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1400855520; called by muse, mutect2, varscan2
- NTM | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs763747307, COSV66174984, COSV66182780; called by muse, mutect2, varscan2
- PCSK1 | c.1095+1G>A p.X365_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as rs1301652826, CS136272, CS136273; called by muse, mutect2, varscan2
- PKD1 | c.4918G>A p.G1640S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.153); catalogued as rs781184044, COSV51917444, COSV99239279; called by muse, mutect2, varscan2
- PLCL1 | c.1922G>C p.R641T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70850256; called by muse, mutect2
- ROBO1 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs552122795; called by muse, mutect2, varscan2
- SLC9C2 | c.2866C>T p.R956C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs776106559, COSV62944078, COSV62948312; called by muse, mutect2, varscan2
- SNAI2 | c.57C>G p.Y19* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV50078850; called by muse, mutect2, varscan2
- SNX5 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs773810235; called by muse, mutect2, varscan2
- SPIB | c.23+3_23+6del p.X8_splice | Splice Site (DEL) | VAF 16/74 reads (22%) | catalogued as rs1419212138; called by mutect2, pindel, varscan2
- UNC5D | c.2323T>A p.F775I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99773389; called by muse, mutect2, varscan2
- WNK4 | c.1222A>T p.I408F | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs369420670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBTB17 | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1444548907; called by muse, mutect2, varscan2
- ZNF385A | c.1046G>T p.R349L (on ENST00000338010 / NM_001130967.3; = p.R329L on NM_015481.3) | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760571183; called by muse, mutect2, varscan2
- ADAMTS12 | c.3044dup p.N1015Kfs*25 | Frame Shift Ins (INS) | VAF 39/98 reads (40%) | called by mutect2, pindel, varscan2
- BAZ2B | c.3023_3032del p.R1008Tfs*2 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- C3orf22 | c.292T>C p.C98R | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC14 | c.1853C>T p.A618V (on ENST00000488653; = p.A570V on NM_022757.5) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CSMD1 | c.7501T>C p.S2501P (on ENST00000520002; = p.S2500P on NM_033225.6) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- DNAH11 | c.5566T>C p.F1856L | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.192); called by muse, mutect2
- GABRA3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HMCN1 | c.3388C>A p.L1130I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGSF9B | c.2566G>A p.G856S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IMPG2 | c.1597T>C p.S533P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LRP1B | c.5312A>C p.E1771A | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- MAP3K1 | c.1358A>T p.E453V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PCDHA13 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PEG3 | c.3632A>G p.N1211S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PMS1 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PTPRD | c.107T>A p.V36D | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RASGRF1 | c.3049A>T p.I1017F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- RNMT | c.722A>T p.E241V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- SNTG1 | c.1039-1G>A p.X347_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- TIMP3 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.2727C>G p.D909E (on ENST00000648592; = p.D875E on NM_182973.2) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- UBR5 | c.6998G>A p.R2333Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- UCK2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- USP9X | c.766A>C p.I256L | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2
- ZIC2 | c.873C>G p.H291Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF695 | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- AR | c.1809T>C p.T603= | Silent (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- CACNB3 | c.1440C>T p.P480= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs1057020451; called by muse, mutect2, varscan2
- CCDC40 | c.1281G>T p.T427= | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- CD1E | c.177G>C p.L59= | Silent (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- CD36 | c.1305T>G p.T435= | Silent (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- DRC1 | c.885G>A p.V295= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1218553246; called by muse, mutect2, varscan2
- GARNL3 | c.111G>A p.T37= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs764382054; called by muse, mutect2, varscan2
- GOLGA5 | c.777A>G p.L259= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- GREB1 | c.5079G>A p.L1693= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1466060128; called by muse, mutect2, varscan2
- HES1 | c.219C>T p.S73= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- KIF26B | c.2775G>A p.T925= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs368334439; called by muse, mutect2, varscan2
- KREMEN1 | c.153C>T p.G51= (on ENST00000407188; = p.G53= on NM_032045.5) | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs371152545; called by muse, mutect2, varscan2
- MMP1 | c.528A>T p.G176= | Silent (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- MUC16 | c.23865G>A p.E7955= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV101199732; called by muse, mutect2, varscan2
- PDP2 | c.945C>T p.A315= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs760619274, COSV61240414; called by muse, mutect2, varscan2
- PIAS2 | c.1032G>A p.L344= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as rs1372467122, COSV61341954; called by muse, mutect2
- PLIN4 | c.3462G>A p.A1154= (on ENST00000301286; = p.A1169= on NM_001367868.2) | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs375540587; called by muse, mutect2, varscan2
- TOP2A | c.1722C>T p.I574= | Silent (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- ZNF816 | c.1303C>A p.R435= | Silent (SNP) | VAF 44/131 reads (34%) | called by muse, mutect2, varscan2
- ZNF835 | c.870C>T p.I290= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as rs1346801547, COSV73379748; called by muse, mutect2
- MIR515-2 | n.29C>A | RNA (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.2421+17G>A | Intron (SNP) | VAF 20/36 reads (56%) | catalogued as rs903318821, COSV53932865; called by muse, mutect2, varscan2
- TTN | c.10361-5173T>C | Intron (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
